Somatic mutation profile of tumor specimen TCGA-CZ-5469-01A (aliquot TCGA-CZ-5469-01A-01D-1501-10) from TCGA case TCGA-CZ-5469, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 41.7 years (15,242 days).
Specimen TCGA-CZ-5469-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 09e844e3-457e-4794-998a-fef696598a60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CZ-5469-11A (Solid Tissue Normal), aliquot TCGA-CZ-5469-11A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8509d3e4-e08b-4ddb-a2f8-9e89517ed363

The open-access MAF lists 43 somatic variants for this specimen: 33 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 9, Nonsense Mutation 2, In Frame Del 1, Splice Site 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKAP13 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 36/172 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs796265954, COSV63467922; called by muse, mutect2, varscan2
- BAP1 | c.509T>G p.F170C | Missense Mutation (SNP) | VAF 37/49 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56239815; called by muse, mutect2, varscan2
- CASKIN2 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs370315404; called by muse, mutect2, varscan2
- CDC25A | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 125/156 reads (80%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV56772071; called by muse, mutect2, varscan2
- CENPM | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53245792; called by muse, mutect2
- CEP68 | c.1814C>A p.P605Q | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.22); catalogued as COSV53127187, COSV99561025; called by muse, mutect2, varscan2
- DCST2 | c.1115C>T p.T372M | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs138904334; called by muse, mutect2, varscan2
- EIF2B1 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1434489925, COSV57459816; called by muse, varscan2
- EIF2B1 | c.85A>T p.T29S | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.084); catalogued as COSV57459822; called by muse, varscan2
- FLYWCH1 | c.911G>A p.C304Y (on ENST00000253928 / NM_001308068.2; = p.C303Y on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54149257; called by muse, mutect2, varscan2
- GON4L | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 81/187 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55202346; called by muse, mutect2
- KIAA0513 | c.1180G>C p.D394H | Missense Mutation (SNP) | VAF 46/120 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV50743794; called by muse, mutect2, varscan2
- KRTAP15-1 | c.139C>A p.L47I | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV61877253; called by muse, mutect2, varscan2
- NEXMIF | c.1030A>G p.T344A | Missense Mutation (SNP) | VAF 49/59 reads (83%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV50087602; called by muse, mutect2, varscan2
- NME9 | c.698C>G p.T233S (on ENST00000333911 / NM_001349024.2; = p.T172S on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.084); catalogued as COSV58622197; called by muse, mutect2, varscan2
- OCA2 | c.590A>C p.Y197S | Missense Mutation (SNP) | VAF 76/135 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.045); catalogued as COSV62356378; called by muse, mutect2, varscan2
- OR10H5 | c.513C>A p.H171Q | Missense Mutation (SNP) | VAF 75/182 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV58279080; called by muse, mutect2, varscan2
- PLXND1 | c.1420G>A p.V474M | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750310939, COSV60718929; called by muse, mutect2
- PREX1 | c.4810C>T p.R1604W | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447178153, COSV64249860; called by muse, mutect2, varscan2
- RIMBP2 | c.181T>C p.F61L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99900731; called by muse, mutect2, varscan2
- RIMS1 | c.954G>T p.R318S | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as COSV53479549; called by muse, mutect2
- RRS1 | c.199G>C p.D67H | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52558633; called by muse, varscan2
- SEZ6 | c.1820C>T p.P607L | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57984286; called by muse, mutect2, varscan2
- SRPK2 | c.89C>G p.P30R | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.229); catalogued as COSV61963739; called by muse, mutect2
- THRAP3 | c.1633C>T p.R545* | Nonsense Mutation (SNP) | VAF 21/55 reads (38%) | catalogued as COSV63569542; called by muse, mutect2, varscan2
- TINAGL1 | c.677G>T p.C226F | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54699890; called by muse, mutect2, varscan2
- WNT2 | c.996C>G p.C332W | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55410863, COSV55413284; called by muse, mutect2, varscan2
- ZBBX | c.1994C>T p.S665L | Missense Mutation (SNP) | VAF 139/637 reads (22%) | SIFT tolerated (0.38); PolyPhen benign (0.089); catalogued as COSV56799495; called by muse, mutect2, varscan2
- ZNF649 | c.667G>A p.E223K | Missense Mutation (SNP) | VAF 83/199 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.24); catalogued as rs1276774444, COSV56817536; called by muse, mutect2, varscan2
- ABCC2 | c.1805_1815+22del p.X602_splice | Splice Site (DEL) | VAF 76/186 reads (41%) | called by mutect2, pindel
- DNAJC13 | c.3633_3644del p.M1211_K1214del | In Frame Del (DEL) | VAF 130/413 reads (31%) | called by mutect2, pindel, varscan2
- KRT73 | c.332dup p.S112Efs*13 | Frame Shift Ins (INS) | VAF 18/77 reads (23%) | called by mutect2, pindel, varscan2
- MRC1 | c.3369C>A p.C1123* | Nonsense Mutation (SNP) | VAF 66/573 reads (12%) | called by muse, mutect2, varscan2
- ANKRD23 | c.771A>G p.K257= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as COSV58413314; called by muse, mutect2, varscan2
- CSF3R | c.270C>T p.P90= | Silent (SNP) | VAF 4/27 reads (15%) | called by muse, varscan2
- GON4L | c.1650A>G p.E550= | Silent (SNP) | VAF 81/190 reads (43%) | catalogued as COSV55202317; called by muse, mutect2
- HIRA | c.1035A>G p.V345= | Silent (SNP) | VAF 6/82 reads (7%) | catalogued as COSV54278710; called by muse, mutect2
- HSPG2 | c.153G>A p.S51= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs370635954; called by muse, mutect2, varscan2
- LARP4 | c.594T>C p.R198= | Silent (SNP) | VAF 24/477 reads (5%) | catalogued as COSV53326625; called by muse, mutect2
- MED12 | c.6129T>C p.R2043= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV61353704; called by muse, mutect2
- NANOG | c.525C>T p.P175= | Silent (SNP) | VAF 68/153 reads (44%) | catalogued as rs758918190, COSV57552487; called by muse, mutect2, varscan2
- OR2C1 | c.141G>A p.L47= | Silent (SNP) | VAF 70/147 reads (48%) | catalogued as COSV59241171; called by muse, mutect2, varscan2
- HAUS7 | c.961-506A>T | Intron (SNP) | VAF 85/96 reads (89%) | catalogued as COSV100444361; called by muse, mutect2, varscan2
